Somatic mutation profile of tumor specimen MP2PRT-PAPAZA-TMP1-A (aliquot MP2PRT-PAPAZA-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPAZA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,967 days).
Specimen MP2PRT-PAPAZA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 527abb53-e72c-455b-9007-b5520740dfee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPAZA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPAZA-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb7a60c-4aa2-4be6-b7e0-2deb1f7ea56b

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 19/179 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- AK5 | c.770G>T p.R257L (on ENST00000354567 / NM_174858.3; = p.R231L on NM_012093.4) | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60971016; called by muse, mutect2, varscan2
- ARHGAP21 | c.4712C>T p.T1571M | Missense Mutation (SNP) | VAF 192/409 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs148071624; called by muse, mutect2, varscan2
- BCLAF3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100503212; called by muse, mutect2, varscan2
- CFAP61 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 158/372 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs780255308, COSV55619741, COSV55624296; called by muse, varscan2
- CXCR4 | c.1031_1032insGAACCCCC p.E345Nfs*24 | Frame Shift Ins (INS) | VAF 40/220 reads (18%) | catalogued as COSV54015322; called by mutect2, pindel, varscan2
- DNAH5 | c.10319C>A p.A3440D | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54209694; called by muse, mutect2, varscan2
- LRRC30 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 99/454 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs764413451; called by muse, mutect2, varscan2
- NRAS | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54738004, COSV54746465; called by muse, mutect2
- C4orf54 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 273/557 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- COL21A1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2
- FAM217B | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, varscan2
- IGKV1D-13 | chr2:90154561 TTAATAGTTACCCTCACACAGTGTTACAAACCC>CCGTAG | Missense Mutation (DEL) | VAF 72/107 reads (67%) | called by pindel, varscan2*
- KRT222 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRRC53 | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 12/400 reads (3%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PKLR | c.507+1dup p.X169_splice | Splice Site (INS) | VAF 131/378 reads (35%) | called by mutect2, pindel, varscan2
- SERPINB7 | c.1081T>C p.F361L | Missense Mutation (SNP) | VAF 215/477 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.8793G>A p.L2931= | Silent (SNP) | VAF 18/466 reads (4%) | catalogued as COSV101262487; called by muse, mutect2
- NUBP1 | c.627C>A p.V209= | Silent (SNP) | VAF 13/187 reads (7%) | catalogued as COSV99297060; called by muse, mutect2
- OR1A2 | c.573C>T p.D191= | Silent (SNP) | VAF 115/248 reads (46%) | catalogued as rs760105962, COSV67936200; called by muse, mutect2, varscan2
- SLC9A4 | c.1234C>A p.R412= | Silent (SNP) | VAF 95/422 reads (23%) | catalogued as rs766908354, COSV54828977; called by muse, mutect2, varscan2
- TENT4B | c.1851G>A p.P617= (on ENST00000561678 / NM_001365323.2; = p.P602= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 143/346 reads (41%) | catalogued as rs755481341, COSV62547598; called by muse, mutect2, varscan2
- EPB41L3 | c.2350-1088G>T | Intron (SNP) | VAF 153/377 reads (41%) | called by muse, mutect2, varscan2
- SNRPG | c.180+703A>T | Intron (SNP) | VAF 77/209 reads (37%) | called by muse, mutect2, varscan2
